Surgical pathology report (de-identified scan), TCGA case TCGA-55-7724, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7724-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type:
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

* Final Report *

Clinical History

Left lung cancer

Specimen

#1 4R
#2 Level 7
#3 4L
#4 2R
#5 Left upper lobe wedge
#6 Level 5
#7 Level 6

Gross Examination

#1 Received fresh labeled 4R are fragments of yellow to black material, in aggregate 0.8 x 0.5 x 0.3 cm. It is completely submitted as single frozen sections.

#2 Received fresh labeled level 7 are two fragments of gray-tan tissue, up to 0.3 x 0.2 x 0.1 cm. Completely submitted as a single frozen section.

#3 Received fresh labeled 4L are fragments of black, focally yellow material, in aggregate 0.8 x 0.5 x 0.3 cm. Completely submitted as a single frozen section.

#4 Received fresh labeled 2R are fragments of yellow to black material in aggregate, 0.4 x 0.4 x 0.3 cm. Completely submitted as a single frozen section.

#5 Received fresh labeled left upper lobe wedge is a 14.0 x 6.0 x up to 3.5 cm wedge of lung with a 15.0 cm long staple line along one edge. The pleura is focally firm and discolored gray-tan over an area of 5.5 x 2.0 cm. Approximately 2.0 cm from the staple line, the pleura is focally retracted. Sectioning demonstrates a 1.2 x 1.0 x 0.8 cm ill-defined, gray-tan mass corresponding to this area. The mass itself is 1.5 cm from the stapled resection margin. The parenchyma is otherwise pink-tan to red-tan, soft and spongy. There are multiple adjacent cystic spaces beneath the firm discolored area on the pleural surface up to 0.5 cm. There are no additional lesions identified. Following consent of the patient, tissue is submitted to the Cancer

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surgical Pathology Report

* Final Report *

Genome Atlas Project. Block Summary: "A", parenchymal margin closest to mass, tangential; "B", "D", mass with respect to pleura (inked black), perpendicular; "E", section of firm discolored area on pleura and cystic spaces; "F", uninvolved parenchyma.

#6 Labeled level 5 is a 1.8 x 1.0 x 0.3 cm portion of gray-tan, soft tissue, entirely submitted in one cassette.

#7 Labeled level 6 is a 1.2 x 0.5 x 0.4 cm portion of gray-tan, soft tissue, entirely submitted in one cassette.

Frozen Section Diagnosis

#1 4R LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY.

#2 LEVEL 7 LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY.

#3 4L LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY.

#4 2R LYMPH NODE BIOPSY (1 FS): NEGATIVE FOR MALIGNANCY.

Microscopic Examination

#1-#6, #7 Microscopic examination performed.

#5 An elastic tissue stain is performed and demonstrates focal invasion of the carcinoma past the elastic tissue layer into the visceral pleura.

Final Diagnosis

#1 4R LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.

#2 LEVEL 7 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.

#3 4L LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.

#4 2R LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.

#5 LEFT UPPER LOBE LUNG, WEDGE, EXCISIONAL BIOPSY: MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA.

TUMOR SIZE: 1.2 X 1.0 X 0.8 CM.

LUNG PARENCHYMAL RESECTION MARGIN STATUS: NEGATIVE FOR CARCINOMA.

PLEURAL STATUS: CARCINOMA INVADES INTO BUT NOT THROUGH VISCERAL

PLEURA

LYMPHOVASCULAR SPACE STATUS: NEGATIVE FOR LYMPHOVASCULAR SPACE

INVASION.

LYMPH NODE STATUS: NONE IDENTIFIED.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT2a PL1 pN0.

#6 LEVEL 5 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.

#7 LEVEL 6 LYMPH NODE BIOPSY: NEGATIVE FOR MALIGNANCY.

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

Signature Line

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file dcc76a75-4dbb-4a86-ae29-b6e57bb178ab (TCGA-55-7724.2D61169F-EAF9-4A67-AFEF-0DD4C2FFE0C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).